MMRF case MMRF_2613 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ce342792-0714-43d5-a342-8e7b3fac2f31

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 621 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.4 years (25,731 days); ISS stage: II; Days to last known disease status: 621 days (1.7 years); Days to last follow up: 621 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 326 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 621 days (1.7 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 326 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 344 days; Days to treatment end: 348 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 344 days; Days to treatment end: 534 days (1.5 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 536 days (1.5 years); Days to treatment end: 575 days (1.6 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 582 days (1.6 years); Days to treatment end: 621 days (1.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 621.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 4.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 57.9 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 3.95 ×10⁹/L; Absolute Neutrophil 2.29 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 66.3 µmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 11.4 g/dL; Glucose 6.22 mmol/L; C-Reactive Protein 0.076 mg/dL.
- Day 74 (ECOG 1): M Protein 2.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.086 mg/dL; Immunoglobulin G 34.4 g/L; Immunoglobulin A 0.063 g/L; Immunoglobulin M 0.057 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 2.16 ×10⁹/L; Absolute Neutrophil 1.38 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 48.6 µmol/L; Calcium 2.28 mmol/L; Total Protein 8.6 g/dL; Glucose 4.84 mmol/L.
- Day 169: M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 0.056 g/L; Immunoglobulin M 0.048 g/L; Beta 2 Microglobulin 1.71 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 47.7 µmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 253: M Protein 1.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 18.1 g/L; Immunoglobulin A 0.091 g/L; Immunoglobulin M 0.063 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.67 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 49.5 µmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 4.79 mmol/L.
- Day 344 (ECOG 0): M Protein 2.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 27.1 g/L; Immunoglobulin A 0.076 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 1.51 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 3.19 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 49.5 µmol/L; Calcium 2.23 mmol/L; Albumin 39.6 g/L; Total Protein 7.8 g/dL; Glucose 7.37 mmol/L.
- Day 456: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.202 g/L; Immunoglobulin M 0.086 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 5.37 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.12 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 44.2 µmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 534 (ECOG 2): M Protein 2.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 51.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.19 mg/dL; Immunoglobulin G 38 g/L; Immunoglobulin A 0.104 g/L; Immunoglobulin M 0.052 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.32 ×10⁹/L; Absolute Neutrophil 1.73 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 57.5 µmol/L; Calcium 2.23 mmol/L; Albumin 34.7 g/L; Total Protein 8.3 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -5: Weight: 83 kg; Height: 152 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_2613_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2613_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
- Sample MMRF_2613_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 344 days.
